Surgical pathology report (de-identified scan), TCGA case TCGA-CC-5264, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-5264-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site: liver, C22.0 1/29/11 *fw*

ID#

Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Liver Tumor	7 x 6 x 5 cm		6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT3 N0 M0		Stage: III	
Notes:			
UUID: 4D5CD8E8-DAD7-4392-A44C-BBDF3DAD872F TCGA-CC-5264-01A-PR Redacted  			

[page 2 of 3]
ID#:

Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse			☒		Streaming						
Mosaic					Storiform						
Necrosis			☒		Fibrosis						
Lymphocytic Infiltration					Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						
Cellular Differentiation											
Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	☒		Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		
Cellular Differentiation: Well Moderate ☒ Poor											
Nuclear Appearance											
Nuclear Atypia:				0	I	II	III				
Aniso Nucleosis					☒						
Hyperchromatism					☒						
Nucleolar Prominent						☒					
Multinucleated Giant Cell						☒					
Mitotic Activity						☒					
Nuclear Grade:											

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Hepatocarcinoma Grade: III

Comments:

Principal Investigator

Pathologist

Date

[page 3 of 3]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		☒	Streaming		
Mosaic	☒		Storiform		
Necrosis		☒	Fibrosis		
Lymphocytic Infiltration	☒		Palisading		
Vascular Invasion		☒	Cystic Degeneration		
Clusterized	☒		Bleeding		
Alveolar Formation	☒		Myxoid Change		
Indian File		☒	Psammoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamous Cell			Glandular cell	☒		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	☒		Fibroblast			Small Cell		
Keratin			Secretion	☒		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	☒		Lipoblast			Inflam. Cell		
Pearl			Gland formation	☒		Myoblast			Plasma Cell		
Otherwise Specified: D1 95% D2 95% D3 95% D4 95%											

2. Cellular Differentiation:

Well	Moderately	Poor
	☒	

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis			☒	
Hyperchromatism		☒		
Nucleolar Prominent		☒		
Multinucleated Giant Cell			☒	
Mitotic Activity			☒	
Nuclear Grade			☒	

Histological Diagnosis: Hepatocellular Carcinoma, G2

Comments: _____

Date

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

Source: NCI Genomic Data Commons file 4e383bda-6986-4e32-848f-e90ac82e8bcf (TCGA-CC-5264.4D5CD8E8-DAD7-4392-A44C-BBDF3DAD872F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).